Somatic mutation profile of tumor specimen BA2114D (aliquot aq-BA2114D) from BEATAML1.0 case 2421, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Chronic myelomonocytic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.5 years (25,009 days).
Specimen BA2114D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c019a6db-b972-46ea-8fd3-2eb9887409b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3005D (Solid Tissue Normal), aliquot aq-BA3005D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/259cb568-01f2-49cf-9657-6dbb4063adb4

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, 3'UTR 2, Intron 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 22/279 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 12/78 reads (15%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, varscan2
- DNAAF5 | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs373336873; called by muse, mutect2
- IGLV3-1 | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as rs527411902; called by muse, mutect2, varscan2
- NPAP1 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139282108; called by muse, mutect2
- OSBPL5 | c.300+5G>T | Splice Region (SNP) | VAF 5/33 reads (15%) | catalogued as rs1328540050; called by muse, mutect2
- CNGA1 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FHAD1 | c.3184G>A p.A1062T | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR158 | c.1878A>G p.I626M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ITM2A | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF6 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MGAT3 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MMRN1 | c.2803T>A p.S935T | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2
- SHISA6 | c.1428C>A p.N476K (on ENST00000409168 / NM_001173461.1; = p.N527K on NM_207386.4) | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2
- TMEM237 | c.1087C>A p.L363I (on ENST00000409883 / NM_001044385.3; = p.L355I on NM_152388.4) | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CBLL2 | c.375G>A p.L125= | Silent (SNP) | VAF 24/159 reads (15%) | catalogued as COSV60369516; called by muse, mutect2, varscan2
- COL4A2 | c.2049A>T p.G683= | Silent (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- HSD17B13 | c.522C>T p.C174= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as rs376717987; called by muse, mutect2, varscan2
- IGKV2-30 | c.189G>A p.Q63= | Silent (SNP) | VAF 16/287 reads (6%) | called by muse, mutect2
- CACNA1F | c.4986+35T>C | Intron (SNP) | VAF 14/191 reads (7%) | catalogued as rs905355438; called by muse, mutect2
- EPOR | c.*492A>G | 3'UTR (SNP) | VAF 34/187 reads (18%) | called by muse, mutect2, varscan2
- FOXP2 | c.*2902_*2905del | 3'UTR (DEL) | VAF 14/113 reads (12%) | catalogued as rs1180318702; called by pindel, varscan2
- LINC00452 | n.612-3437C>A | Intron (SNP) | VAF 25/210 reads (12%) | called by muse, mutect2, varscan2
